Gene-level copy-number profile of tumor specimen TCGA-69-7760-01A from TCGA case TCGA-69-7760, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.3 years (26,777 days).
Specimen TCGA-69-7760-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.246572d8-fe00-4c4a-b68e-27daad6dce5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7760-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2dc672c6-e354-40c6-9a6d-825d05c29fd0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,279; copy number 2: 15,168; copy number 3: 25,577; copy number 4: 9,789; copy number 5: 5,129; copy number 6: 733; copy number 7: 724; copy number 8: 504; copy number 9: 580; copy number 10: 28; copy number 11: 15; copy number 12: 164; copy number 15: 45; copy number 18: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7760-01A-11D-2166-01): tumor purity 0.65, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–1): PTPRD.
- chr9:8,797,135–9,442,380, 5 genes: RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,135 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:217,631,324–238,538,305, 482 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:70,972–63,456,687, 1,111 genes, copy number 8–15 (broad region; genes not listed).
- chr8:38,901,235–40,402,010, 28 genes, copy number 10 (within-gene range 1–10): PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr8:41,426,655–43,674,591, 75 genes, copy number 18 (broad region; genes not listed).
- chr8:47,260,878–48,824,062, 28 genes, copy number 7–12 (within-gene range 3–12): SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1.
- chr8:55,067,585–56,253,372, 25 genes, copy number 7: AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1.
- chr8:107,499,773–107,648,032, 2 genes, copy number 8: AC091010.1, PGAM1P13.
- chr8:107,884,494–107,884,611, 1 gene, copy number 8: RNA5SP275.
- chr12:62,935,701–81,759,553, 322 genes, copy number 7–12 (within-gene range 6–12) (broad region; genes not listed).
- chr12:82,358,528–84,449,878, 15 genes, copy number 11 (within-gene range 6–11): METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1.
- chr14:30,734,926–32,882,830, 46 genes, copy number 9: AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.

Autosomal genes at a single copy (total copy number 1): 1,276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
